Somatic mutation profile of tumor specimen TCGA-42-2590-01A (aliquot TCGA-42-2590-01A-01D-1526-09) from TCGA case TCGA-42-2590, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 57.4 years (20,965 days).
Specimen TCGA-42-2590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a5b9452-76bd-460e-a53b-b295850e7e85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2590-10A (Blood Derived Normal), aliquot TCGA-42-2590-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1025148-90dc-42a9-b290-ffd5510ab13b

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 10, Frame Shift Del 2, 5'Flank 1, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 110/163 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1367098860, COSV63022162; called by muse, mutect2, varscan2
- ADGRE3 | c.874C>G p.H292D | Missense Mutation (SNP) | VAF 286/710 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV53732409; called by muse, mutect2, varscan2
- AFF2 | c.2855C>A p.T952N | Missense Mutation (SNP) | VAF 142/412 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV53997111; called by muse, mutect2, varscan2
- AP1B1 | c.2833A>G p.T945A | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV58020056; called by muse, mutect2, varscan2
- ATP8B4 | c.3240G>T p.M1080I | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV52719159; called by muse, mutect2, varscan2
- CCL8 | c.263A>T p.K88M | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67014097; called by muse, mutect2, varscan2
- CDH1 | c.662A>T p.D221V | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55732083, COSV55736188; called by muse, mutect2, varscan2
- CLEC4F | c.1016A>T p.K339I | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55480286; called by muse, mutect2, varscan2
- CSMD3 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 32/1294 reads (2%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV99843764; called by muse, mutect2
- DCAF4L1 | c.272A>C p.Q91P | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV60787816; called by muse, mutect2, varscan2
- DNAH3 | c.8772G>C p.Q2924H | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as COSV54533594; called by muse, mutect2, varscan2
- DPT | c.38T>A p.V13D | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV63190309; called by muse, mutect2, varscan2
- EYS | c.1751A>T p.E584V | Missense Mutation (SNP) | VAF 110/413 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV60992139; called by muse, mutect2, varscan2
- GPR143 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1026812853, COSV66632766; called by muse, mutect2, varscan2
- GSG1L | c.898+1G>A p.X300_splice (on ENST00000447459 / NM_001109763.2; = p.X145_splice on NM_144675.2) | Splice Site (SNP) | VAF 172/466 reads (37%) | catalogued as rs755895622, COSV66575677, COSV99062640; called by mutect2, varscan2
- HDAC6 | c.3244G>A p.G1082R | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61929710; called by muse, mutect2, varscan2
- HS3ST1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50024313; called by muse, mutect2, varscan2
- IGF2BP1 | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs200362453, COSV51733339; called by muse, mutect2, varscan2
- KMT2E | c.2792A>G p.Y931C | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV57576216; called by muse, mutect2, varscan2
- KRT24 | c.617T>A p.I206N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV52880907; called by muse, mutect2, varscan2
- LEFTY1 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV55283466; called by muse, mutect2, varscan2
- LIG1 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 125/222 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV54393603; called by muse, mutect2, varscan2
- LRRIQ1 | c.2163A>T p.E721D | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV67833942; called by muse, mutect2, varscan2
- MAMLD1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 48/167 reads (29%) | catalogued as COSV53375270; called by muse, mutect2, varscan2
- MBP | c.866A>T p.K289M (on ENST00000355994 / NM_001025101.2; = p.K171M on NM_002385.3) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV62829814; called by muse, mutect2, varscan2
- MED13L | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV56124108; called by muse, mutect2, varscan2
- METTL26 | c.123C>A p.H41Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57010876; called by muse, mutect2, varscan2
- MFSD5 | c.977T>A p.L326H | Missense Mutation (SNP) | VAF 56/604 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs1344015863, COSV100289080; called by muse, mutect2
- MRPS23 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 97/357 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV58032507; called by muse, mutect2, varscan2
- NEK5 | c.1915C>G p.P639A | Missense Mutation (SNP) | VAF 123/282 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV62880921; called by muse, mutect2, varscan2
- NFASC | c.2497G>C p.V833L (on ENST00000339876 / NM_001378329.1; = p.V936L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 258/887 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV58371339; called by muse, mutect2, varscan2
- PIGV | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV50294792; called by muse, mutect2, varscan2
- PLCL1 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.737); catalogued as COSV101407090; called by muse, mutect2
- POLB | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55347479; called by muse, mutect2, varscan2
- PPP1R16B | c.1014C>G p.S338R | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100239852, COSV55380047; called by muse, mutect2, varscan2
- RASGRF2 | c.3080T>C p.L1027P | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750065126, COSV54133582; called by muse, mutect2, varscan2
- RNF19A | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100347810; called by muse, mutect2
- RTN4 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1193760146, COSV58269983; called by muse, mutect2, varscan2
- SRRT | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 113/558 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.255); catalogued as COSV61453373; called by muse, mutect2, varscan2
- TBX15 | c.380A>G p.H127R (on ENST00000369429 / NM_001330677.2; = p.H21R on NM_152380.3) | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52873261; called by muse, mutect2, varscan2
- TEAD2 | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60544824; called by muse, mutect2, varscan2
- TES | c.1118A>C p.Q373P | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100829326; called by muse, mutect2
- TP53 | c.1028del p.E343Gfs*2 | Frame Shift Del (DEL) | VAF 49/112 reads (44%) | catalogued as COSV52822268, COSV99436358; called by mutect2, pindel, varscan2
- USH2A | c.4424T>A p.V1475D | Missense Mutation (SNP) | VAF 72/421 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV56395911; called by muse, mutect2, varscan2
- VWA8 | c.2367G>T p.K789N | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55700038; called by muse, mutect2, varscan2
- ZNF445 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV101253800; called by muse, mutect2
- FCGBP | c.5579C>A p.S1860Y | Missense Mutation (SNP) | VAF 92/558 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GIMAP7 | c.688_695del p.E230* | Frame Shift Del (DEL) | VAF 130/225 reads (58%) | called by mutect2, pindel, varscan2
- ATP2A3 | c.936G>T p.P312= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV59231478; called by muse, mutect2, varscan2
- CHRM3 | c.69C>T p.S23= | Silent (SNP) | VAF 46/314 reads (15%) | catalogued as COSV55094467; called by muse, mutect2, varscan2
- CYFIP1 | c.1590C>T p.D530= | Silent (SNP) | VAF 52/160 reads (33%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>A p.A161= | Silent (SNP) | VAF 105/435 reads (24%) | catalogued as rs1369010251, COSV60480151; called by muse, mutect2, varscan2
- OR2Y1 | c.888G>T p.V296= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV57137258; called by muse, mutect2, varscan2
- OR7A10 | c.114T>A p.T38= | Silent (SNP) | VAF 99/222 reads (45%) | catalogued as COSV50166166, COSV50166513; called by muse, mutect2, varscan2
- RYR1 | c.4095A>T p.G1365= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV62102798; called by muse, mutect2, varscan2
- TOMM70 | c.1059T>C p.D353= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as COSV99424407; called by muse, mutect2
- TRNAU1AP | c.363C>T p.P121= | Silent (SNP) | VAF 79/418 reads (19%) | catalogued as rs369255848; called by muse, mutect2, varscan2
- ZBTB39 | c.24A>G p.Q8= | Silent (SNP) | VAF 89/382 reads (23%) | catalogued as COSV55629889; called by muse, mutect2, varscan2
- AP3S1 | chr5:115841614 C>A | 5'Flank (SNP) | VAF 11/74 reads (15%) | catalogued as COSV57243426; called by muse, mutect2, varscan2
- LINC02872 | n.187G>C | RNA (SNP) | VAF 59/182 reads (32%) | called by muse, mutect2, varscan2
